Somatic mutation profile of tumor specimen TCGA-DJ-A1QN-01A (aliquot TCGA-DJ-A1QN-01A-11D-A14W-08) from TCGA case TCGA-DJ-A1QN, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 42.0 years (15,343 days).
Specimen TCGA-DJ-A1QN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed240029-1af2-484b-b39a-5cc8fb33b5f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A1QN-10A (Blood Derived Normal), aliquot TCGA-DJ-A1QN-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1fc29ec-34b7-4e87-8e5a-c51b985ebf94

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- EVPL | c.2725C>T p.Q909* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV56909717; called by muse, mutect2, varscan2
- NDST2 | c.1997A>G p.N666S | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs764136804, COSV55213885; called by muse, mutect2, varscan2
- SLC5A2 | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755101109, COSV57891045; called by muse, mutect2, varscan2
- AUP1 | c.1117del p.L373* | Frame Shift Del (DEL) | VAF 6/77 reads (8%) | called by mutect2, pindel*
- PREB | c.105C>T p.G35= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV53205564; called by muse, mutect2, varscan2
